Somatic mutation profile of tumor specimen C3L-03463-01 (aliquot CPT0190010006) from CPTAC case C3L-03463, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 62.8 years (22,953 days).
Specimen C3L-03463-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ff82eb7-6a47-4635-8be2-50ceb96e8987.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03463-31 (Blood Derived Normal), aliquot CPT0191080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d12899bd-ecff-436b-b529-96b950a62f69

The open-access MAF lists 310 somatic variants for this specimen: 209 protein-altering or splice-affecting, 62 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 188, Silent 62, Intron 17, Nonsense Mutation 11, RNA 10, 5'Flank 6, Splice Site 4, Frame Shift Del 4, 5'UTR 3, 3'Flank 2, Nonstop Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 47/314 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.598-1G>T p.X200_splice | Splice Site (SNP) | VAF 22/85 reads (26%) | hotspot (GDC flag); catalogued as COSV58821045, COSV58823557; called by muse, mutect2, varscan2
- ABCB9 | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1227816766; called by muse, mutect2, varscan2
- ACTRT1 | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 16/151 reads (11%) | catalogued as COSV100947558; called by muse, mutect2, varscan2
- ALKBH1 | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99380628; called by muse, mutect2, varscan2
- ANO1 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV60287711; called by muse, mutect2, varscan2
- ARSF | c.791G>C p.G264A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV100839471; called by muse, varscan2
- CAPN12 | c.948G>T p.K316N | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.871); catalogued as COSV100185076; called by muse, mutect2
- CCNH | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140234729; called by muse, mutect2, varscan2
- CDH8 | c.2258G>T p.G753V | Missense Mutation (SNP) | VAF 36/283 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100179910, COSV100184518, COSV54905279; called by muse, mutect2, varscan2
- CITED2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 37/255 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs753282863; called by muse, mutect2, varscan2
- CLCN1 | c.2878C>G p.P960A | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58369795; called by muse, mutect2, varscan2
- COL6A5 | c.5240G>T p.C1747F | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1372386902; called by muse, mutect2
- CSMD3 | c.5102G>T p.C1701F (on ENST00000297405 / NM_001363185.1; = p.C1597F on NM_052900.3) | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52308972; called by muse, mutect2
- CT47B1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 92/735 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as rs9698608, COSV100989020, COSV64891022; called by muse, mutect2, varscan2
- DCAF12L1 | c.568C>A p.R190S | Missense Mutation (SNP) | VAF 59/428 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.488); catalogued as rs757985768, COSV100948252, COSV64421466; called by muse, mutect2, varscan2
- DCAF12L2 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63583736; called by muse, mutect2
- DCSTAMP | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 34/504 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV99886228; called by muse, mutect2
- DST | c.7813G>A p.G2605R | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs761457855, COSV54996175; called by muse, mutect2, varscan2
- EML5 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100715357; called by muse, mutect2
- ERBB4 | c.3019C>T p.L1007F | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100721959; called by muse, mutect2, varscan2
- EYS | c.4203T>A p.D1401E | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.321); catalogued as rs1562080367; called by muse, mutect2, varscan2
- F5 | c.4369C>T p.P1457S | Missense Mutation (SNP) | VAF 47/407 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs1321150541, COSV63124034; called by muse, mutect2, varscan2
- FAT1 | c.7663G>T p.D2555Y | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71672091; called by muse, mutect2, varscan2
- FCRL5 | c.1819C>A p.L607M | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62511647; called by muse, mutect2
- FNDC1 | c.2437G>A p.A813T | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as COSV51945161; called by muse, mutect2
- GBA3 | c.1281G>T p.Q427H | Missense Mutation (SNP) | VAF 43/383 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV72437949; called by muse, mutect2, varscan2
- GPR37 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs369730075; called by muse, mutect2
- GPX6 | c.511T>A p.W171R | Missense Mutation (SNP) | VAF 62/400 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100724793; called by muse, mutect2, varscan2
- IGHM | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 156/750 reads (21%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.617); catalogued as rs782230332; called by mutect2, varscan2
- IGHMBP2 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 55/368 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs374952782; called by muse, mutect2, varscan2
- JAKMIP1 | c.343G>T p.A115S | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV51531491; called by muse, mutect2
- KCNH5 | c.1258G>T p.V420L | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV100526701; called by muse, mutect2, varscan2
- MAGEB1 | c.87C>A p.H29Q | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66775520; called by muse, mutect2, varscan2
- MAN1B1 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 16/360 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.185); catalogued as rs1442423118; called by muse, mutect2
- MED12L | c.2462C>A p.S821Y | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99853779; called by muse, mutect2, varscan2
- NLRP7 | c.2333G>T p.W778L (on ENST00000340844 / NM_206828.3; = p.W750L on NM_139176.3) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100052734; called by muse, mutect2, varscan2
- NPS | c.7A>C p.S3R | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV101219361; called by muse, mutect2, varscan2
- OR2M2 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV100677357; called by muse, varscan2
- OR2M5 | c.136G>T p.V46F | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV63546695; called by muse, mutect2
- OR51D1 | c.660G>T p.M220I | Missense Mutation (SNP) | VAF 97/579 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.267); catalogued as rs1043962012; called by muse, mutect2, varscan2
- OR52E4 | c.685C>T p.L229F | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs1424205905; called by muse, mutect2
- PAX2 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1454668545; called by muse, mutect2
- PGK2 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV59164901, COSV59165073; called by muse, mutect2, varscan2
- PIP | c.60C>A p.C20* | Nonsense Mutation (SNP) | VAF 23/249 reads (9%) | catalogued as COSV52120424; called by muse, mutect2
- PLAAT5 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as COSV57136043; called by muse, mutect2, varscan2
- PRKD1 | c.1392G>T p.K464N | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100119818, COSV59561752; called by muse, mutect2
- PTPRD | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 27/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61941130; called by muse, mutect2
- RGP1 | c.626G>C p.R209P | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65239298, COSV65239971; called by muse, mutect2, varscan2
- SERPINE1 | c.881G>T p.R294L | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV56171097; called by muse, mutect2
- SHROOM4 | c.1729C>A p.R577S | Missense Mutation (SNP) | VAF 86/565 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99173004; called by muse, mutect2, varscan2
- SLC22A6 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.085); catalogued as COSV100842900, COSV64560855; called by muse, mutect2, varscan2
- SLC30A8 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69975285; called by muse, mutect2
- SLC8A2 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99370399; called by muse, mutect2, varscan2
- SOBP | c.1295C>T p.P432L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs753251579; called by muse, mutect2, varscan2
- SOX3 | c.483C>G p.N161K | Missense Mutation (SNP) | VAF 55/457 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65168816; called by muse, mutect2, varscan2
- SPHKAP | c.3268G>T p.D1090Y | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60886206; called by muse, mutect2
- STAC2 | c.1085T>C p.F362S | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs1567827157; called by muse, mutect2
- STARD8 | c.712A>G p.S238G | Missense Mutation (SNP) | VAF 45/325 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV52926524; called by muse, mutect2, varscan2
- TLL1 | c.2919G>T p.E973D | Missense Mutation (SNP) | VAF 57/325 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.325); catalogued as COSV50265253, COSV50285293; called by muse, mutect2, varscan2
- TMC7 | c.45C>A p.S15R | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1020037578; called by muse, mutect2, varscan2
- TSHZ2 | c.1327C>A p.P443T | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV61591916; called by muse, mutect2, varscan2
- WAS | c.176del p.P59Lfs*17 | Frame Shift Del (DEL) | VAF 63/425 reads (15%) | catalogued as CM043602, CM102369; called by mutect2, pindel, varscan2
- ZFP14 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV54202506; called by muse, mutect2
- ZNF592 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 76/656 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs924341325; called by muse, mutect2, varscan2
- ZRANB3 | c.484A>G p.M162V | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs773133866; called by muse, mutect2, varscan2
- ABL1 | c.1983G>C p.K661N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- AC093155.3 | c.46+1G>T p.X16_splice | Splice Site (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- ADCK1 | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- AL592490.1 | c.1706A>G p.Q569R | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- AMPH | c.1834G>T p.A612S | Missense Mutation (SNP) | VAF 29/262 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD11 | c.4535G>T p.R1512L | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANO4 | c.796C>T p.H266Y (on ENST00000392977 / NM_001286615.2; = p.H231Y on NM_178826.4) | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.95); called by muse, mutect2
- ANXA5 | c.13del p.L5Sfs*5 | Frame Shift Del (DEL) | VAF 40/232 reads (17%) | called by mutect2, pindel, varscan2
- ARHGAP20 | c.2999G>T p.G1000V | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- ARHGEF11 | c.3664A>G p.M1222V | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2
- ARIH1 | c.955-1G>A p.X319_splice | Splice Site (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- ASXL3 | c.2105C>A p.S702Y | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- ATM | c.8020A>T p.T2674S | Missense Mutation (SNP) | VAF 35/285 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ATP8A1 | c.3160G>T p.G1054C | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.317); called by muse, mutect2
- AUTS2 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BFAR | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- BRIP1 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.299); called by muse, mutect2
- CABYR | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CACNA2D3 | c.2755G>T p.G919C | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- CCKBR | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 65/374 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- CD44 | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 67/464 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDC14C | c.546T>A p.N182K (on ENST00000428251; = p.N75K on NM_152627.3) | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.166); called by muse, mutect2
- CDH1 | c.2021A>G p.N674S | Missense Mutation (SNP) | VAF 71/521 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CDH2 | c.1398T>A p.N466K | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CDK17 | c.1442A>G p.H481R | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2
- CDK9 | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 18/275 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- CHD9 | c.7891G>T p.G2631W (on ENST00000398510 / NM_001382353.1; = p.G2615W on NM_025134.7) | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC12B | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CMKLR1 | c.637G>T p.G213W (on ENST00000312143 / NM_001142344.2; = p.G211W on NM_004072.3) | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CNTN6 | c.307A>T p.T103S | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.087); called by muse, mutect2
- COL11A2 | c.1274C>T p.P425L (on ENST00000341947 / NM_080680.3; = p.P318L on NM_080679.2) | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- COL3A1 | c.2626G>T p.G876C | Missense Mutation (SNP) | VAF 85/354 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD1 | c.3620A>T p.Q1207L (on ENST00000520002; = p.Q1206L on NM_033225.6) | Missense Mutation (SNP) | VAF 7/177 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- CSMD3 | c.6029C>G p.S2010* (on ENST00000297405 / NM_001363185.1; = p.S1906* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 46/270 reads (17%) | called by muse, mutect2, varscan2
- CSRNP3 | c.1758G>T p.*586Yext*1 | Nonstop Mutation (SNP) | VAF 14/74 reads (19%) | called by muse, varscan2
- CYP1B1 | c.1184T>G p.V395G | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DBH | c.21G>A p.W7* | Nonsense Mutation (SNP) | VAF 21/218 reads (10%) | called by muse, mutect2
- DCANP1 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- DNAAF1 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 61/318 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH9 | c.7142C>A p.A2381D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DOCK4 | c.2441A>T p.K814I | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2
- DPH1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); called by muse, mutect2
- DYRK2 | c.1315G>A p.G439S (on ENST00000344096 / NM_006482.3; = p.G366S on NM_003583.4) | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- DYRK2 | c.1316G>T p.G439V (on ENST00000344096 / NM_006482.3; = p.G366V on NM_003583.4) | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ELAC2 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 23/544 reads (4%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.731); called by muse, mutect2
- ELK1 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 35/321 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ENTPD3 | c.275G>T p.C92F | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA3 | c.1484C>A p.T495N | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM47B | c.903G>C p.E301D | Missense Mutation (SNP) | VAF 63/480 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FREM1 | c.5492C>A p.S1831Y | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- FRMPD4 | c.1684G>T p.G562C | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.541); called by muse, mutect2
- FSIP2 | c.15502C>A p.H5168N | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.223); called by muse, mutect2
- FSTL5 | c.2461C>A p.L821I | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.685); called by muse, mutect2
- GALNT14 | c.398+1G>T p.X133_splice | Splice Site (SNP) | VAF 16/137 reads (12%) | called by muse, mutect2, varscan2
- GALNT14 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATA1 | c.1079C>A p.T360N | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- GPR37 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- GPR82 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GPR82 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- GRID1 | c.2675A>T p.Q892L | Missense Mutation (SNP) | VAF 23/287 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- HAS1 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, mutect2
- HAS1 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 24/425 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2
- HCFC1 | c.4699G>T p.V1567L | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HRNR | c.1642C>A p.H548N | Missense Mutation (SNP) | VAF 180/791 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IMP3 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.524); called by muse, mutect2
- JAK3 | c.700C>G p.L234V | Missense Mutation (SNP) | VAF 12/384 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- KAT14 | c.1534G>T p.D512Y | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNB2 | c.1939A>T p.R647W | Missense Mutation (SNP) | VAF 54/250 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- KHDRBS1 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.05); called by muse, mutect2
- KRTAP5-11 | c.358A>T p.S120C | Missense Mutation (SNP) | VAF 46/814 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- LIN9 | c.608A>G p.D203G (on ENST00000366808 / NM_001270410.2; = p.D148G on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LMTK2 | c.3649A>T p.T1217S | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.026); called by mutect2, varscan2
- MAJIN | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP2 | c.5317G>C p.D1773H | Missense Mutation (SNP) | VAF 65/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP7D3 | c.1857A>C p.E619D | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MASP1 | c.816C>A p.S272R | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MCM9 | c.1225G>T p.G409C | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MMP27 | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRGPRX1 | c.841C>A p.R281S | Missense Mutation (SNP) | VAF 39/472 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2
- MROH2A | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTMR3 | c.2847G>T p.Q949H | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- MTRNR2L5 | c.68G>C p.R23P | Missense Mutation (SNP) | VAF 15/76 reads (20%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH15 | c.437A>T p.Y146F | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MYH2 | c.4909C>A p.H1637N | Missense Mutation (SNP) | VAF 70/366 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- MYO1B | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2
- NBR1 | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- NCR1 | c.98C>A p.A33D | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLGN4X | c.824A>G p.K275R | Missense Mutation (SNP) | VAF 74/429 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- NLRP10 | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- OBSCN | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2
- OBSCN | c.12683G>T p.G4228V | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ODF3L2 | c.531del p.K177Nfs*74 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel*, varscan2
- OGT | c.1921G>T p.G641C | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR3A2 | c.716C>G p.S239* | Nonsense Mutation (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- OR52B4 | c.863T>C p.M288T | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- PAK1IP1 | c.1092A>C p.E364D | Missense Mutation (SNP) | VAF 14/329 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); called by muse, mutect2
- PAPPA | c.1297A>C p.T433P | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCARE | c.3538G>T p.A1180S | Missense Mutation (SNP) | VAF 44/534 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2
- PFKFB1 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 22/169 reads (13%) | PolyPhen benign (0.388); called by muse, mutect2, varscan2
- PIK3C2G | c.3457C>A p.L1153M (on ENST00000676171; = p.L1112M on NM_004570.5) | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PJA1 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLB1 | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPFIBP1 | c.560A>G p.E187G | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2
- PRR22 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PRR33 | c.956C>A p.T319N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.053); called by muse, mutect2
- PRRC2A | c.4205G>T p.G1402V | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2
- PRSS56 | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD21L1 | c.1497G>T p.M499I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2
- RAD9B | c.575G>C p.S192T | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- RIPK1 | c.792G>T p.M264I | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF113A | c.615C>G p.Y205* | Nonsense Mutation (SNP) | VAF 13/428 reads (3%) | called by muse, mutect2
- RYR3 | c.6481A>T p.K2161* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | called by muse, mutect2
- SALL3 | c.2498C>A p.P833Q | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SCAF1 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- SETX | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- SH2D1A | c.317C>G p.S106C | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHISA7 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2
- SLC26A1 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 17/356 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SLITRK5 | c.886C>G p.P296A | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2
- SMPDL3A | c.943G>T p.V315L | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SNX25 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 27/344 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.048); called by muse, mutect2
- SPEN | c.9358C>T p.P3120S | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- STK17B | c.634A>T p.I212F | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TANC2 | c.5006G>T p.G1669V | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.994); called by muse, mutect2
- TCF25 | c.1514G>T p.R505M | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCN2 | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.921); called by muse, mutect2
- TDRD9 | c.3741T>A p.Y1247* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- TNPO2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TRAV19 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 54/306 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- TROAP | c.1194G>T p.Q398H | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TRPM6 | c.1313A>T p.D438V | Missense Mutation (SNP) | VAF 27/382 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2
- UNC93A | c.462G>T p.L154F | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- URB2 | c.2194G>T p.G732* | Nonsense Mutation (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- UROC1 | c.223T>A p.Y75N | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- USH2A | c.7189G>T p.V2397L | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- WDR77 | c.204del p.N69Tfs*27 | Frame Shift Del (DEL) | VAF 24/230 reads (10%) | called by mutect2, varscan2
- XYLT2 | c.1940A>T p.E647V | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, varscan2
- ZNF160 | c.1080G>T p.Q360H | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); called by muse, mutect2
- ZNF469 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZNF479 | c.812G>T p.C271F | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF536 | c.3629A>G p.Q1210R | Missense Mutation (SNP) | VAF 9/271 reads (3%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.012); called by muse, mutect2
- ZNF74 | c.342A>T p.P114= | Splice Region (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2, varscan2
- ZSCAN5B | c.1387G>T p.G463* | Nonsense Mutation (SNP) | VAF 34/286 reads (12%) | called by muse, mutect2, varscan2
- ABCA13 | c.6378A>C p.T2126= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- BTN3A1 | c.1113G>T p.L371= | Silent (SNP) | VAF 54/328 reads (16%) | called by muse, mutect2, varscan2
- CACNA1F | c.3675C>A p.L1225= | Silent (SNP) | VAF 61/462 reads (13%) | called by muse, mutect2, varscan2
- CCDC136 | c.2334C>T p.S778= | Silent (SNP) | VAF 18/477 reads (4%) | called by muse, mutect2
- CCNT1 | c.1509C>T p.S503= | Silent (SNP) | VAF 46/425 reads (11%) | called by muse, mutect2, varscan2
- CDH19 | c.879C>T p.Y293= | Silent (SNP) | VAF 25/191 reads (13%) | called by muse, mutect2, varscan2
- CDHR2 | c.1599C>T p.P533= | Silent (SNP) | VAF 19/351 reads (5%) | catalogued as rs368141315; called by muse, mutect2
- CEBPB | c.267G>T p.A89= | Silent (SNP) | VAF 17/110 reads (15%) | called by muse, mutect2, varscan2
- CFAP65 | c.1845C>A p.P615= | Silent (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- CHD3 | c.1167G>A p.G389= | Silent (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- CHRM3 | c.450A>T p.V150= | Silent (SNP) | VAF 53/206 reads (26%) | called by muse, mutect2, varscan2
- CSPG4 | c.5997C>A p.A1999= | Silent (SNP) | VAF 34/256 reads (13%) | called by muse, mutect2, varscan2
- EPHA3 | c.1485C>A p.T495= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV60708362; called by muse, mutect2, varscan2
- FAT3 | c.1282C>T p.L428= | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as COSV99961568; called by muse, mutect2, varscan2
- FLNC | c.930G>T p.V310= | Silent (SNP) | VAF 54/467 reads (12%) | called by muse, mutect2, varscan2
- GCN1 | c.1968C>T p.L656= | Silent (SNP) | VAF 28/246 reads (11%) | catalogued as COSV56115771; called by muse, mutect2, varscan2
- GLB1 | c.615G>A p.K205= | Silent (SNP) | VAF 12/305 reads (4%) | catalogued as rs1427461485; called by muse, mutect2
- HAS2 | c.997C>A p.R333= | Silent (SNP) | VAF 31/439 reads (7%) | catalogued as rs777496685, COSV58265301; called by muse, mutect2
- HOXD12 | c.618G>T p.R206= | Silent (SNP) | VAF 44/290 reads (15%) | called by muse, mutect2, varscan2
- IGHM | c.537C>G p.T179= | Silent (SNP) | VAF 153/761 reads (20%) | called by muse, mutect2, varscan2
- ITIH1 | c.246C>T p.A82= | Silent (SNP) | VAF 30/252 reads (12%) | called by muse, mutect2, varscan2
- LIMA1 | c.270A>G p.L90= | Silent (SNP) | VAF 39/247 reads (16%) | catalogued as rs139678259; called by muse, mutect2, varscan2
- LONRF3 | c.582G>C p.L194= | Silent (SNP) | VAF 57/363 reads (16%) | called by muse, mutect2, varscan2
- LRATD1 | c.273C>A p.G91= | Silent (SNP) | VAF 24/207 reads (12%) | called by muse, mutect2, varscan2
- MGAT1 | c.1074C>T p.F358= | Silent (SNP) | VAF 16/356 reads (4%) | called by muse, mutect2
- MMP27 | c.666G>T p.L222= | Silent (SNP) | VAF 19/160 reads (12%) | called by muse, mutect2, varscan2
- NECTIN2 | c.201G>A p.L67= | Silent (SNP) | VAF 11/326 reads (3%) | called by muse, mutect2
- NOM1 | c.756G>A p.E252= | Silent (SNP) | VAF 48/330 reads (15%) | called by muse, varscan2
- NSDHL | c.327A>T p.P109= | Silent (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2, varscan2
- NUAK1 | c.1056G>T p.L352= | Silent (SNP) | VAF 30/182 reads (16%) | called by muse, mutect2, varscan2
- OR14A16 | c.111G>C p.L37= | Silent (SNP) | VAF 35/211 reads (17%) | catalogued as COSV62926524; called by muse, mutect2, varscan2
- OR2G6 | c.501C>T p.P167= | Silent (SNP) | VAF 49/275 reads (18%) | called by muse, mutect2, varscan2
- OR2L2 | c.660T>A p.V220= | Silent (SNP) | VAF 17/385 reads (4%) | called by muse, mutect2
- OR52E4 | c.684C>A p.R228= | Silent (SNP) | VAF 28/340 reads (8%) | called by muse, mutect2
- OR7D4 | c.672C>A p.S224= | Silent (SNP) | VAF 37/249 reads (15%) | called by muse, mutect2, varscan2
- OR8H2 | c.375G>A p.A125= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as rs1425546691; called by muse, mutect2, varscan2
- OTOG | c.843C>T p.T281= | Silent (SNP) | VAF 57/381 reads (15%) | called by muse, mutect2, varscan2
- PCDHB6 | c.195T>A p.V65= | Silent (SNP) | VAF 32/416 reads (8%) | called by muse, mutect2
- PCDHGA12 | c.1677G>T p.A559= | Silent (SNP) | VAF 20/434 reads (5%) | catalogued as COSV52751348; called by muse, mutect2
- PCSK9 | c.1227C>T p.A409= | Silent (SNP) | VAF 47/375 reads (13%) | catalogued as rs146924245; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PIEZO2 | c.6177C>A p.S2059= | Silent (SNP) | VAF 38/370 reads (10%) | called by muse, mutect2, varscan2
- PLB1 | c.1785T>A p.A595= | Silent (SNP) | VAF 53/252 reads (21%) | called by muse, mutect2, varscan2
- PLCD3 | c.2232C>T p.P744= | Silent (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- PPOX | c.972C>A p.A324= | Silent (SNP) | VAF 117/634 reads (18%) | catalogued as COSV57092085; called by muse, mutect2, varscan2
- RBM10 | c.1122C>T p.G374= | Silent (SNP) | VAF 66/388 reads (17%) | called by muse, mutect2, varscan2
- RBMXL3 | c.714G>T p.R238= | Silent (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2, varscan2
- RELN | c.3588G>A p.R1196= | Silent (SNP) | VAF 43/384 reads (11%) | called by muse, mutect2, varscan2
- RFPL4AL1 | c.150T>G p.R50= | Silent (SNP) | VAF 36/654 reads (6%) | called by muse, mutect2
- RIOX2 | c.240G>T p.L80= | Silent (SNP) | VAF 31/343 reads (9%) | called by muse, mutect2
- RYR2 | c.81C>A p.T27= | Silent (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- RYR2 | c.4428G>T p.V1476= | Silent (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- SIM1 | c.474C>A p.R158= | Silent (SNP) | VAF 20/198 reads (10%) | catalogued as rs762934961; called by muse, mutect2, varscan2
- SLITRK5 | c.798C>A p.T266= | Silent (SNP) | VAF 20/190 reads (11%) | called by muse, mutect2, varscan2
- SLITRK5 | c.888G>A p.P296= | Silent (SNP) | VAF 28/180 reads (16%) | catalogued as rs551991029, COSV61521185; called by muse, mutect2
- SLX4 | c.2925G>A p.P975= | Silent (SNP) | VAF 28/224 reads (13%) | catalogued as rs1431725463; called by muse, mutect2, varscan2
- TACR3 | c.1011C>A p.V337= | Silent (SNP) | VAF 15/168 reads (9%) | catalogued as COSV59198826; called by muse, mutect2
- TEKT4 | c.75G>T p.T25= | Silent (SNP) | VAF 38/313 reads (12%) | called by muse, mutect2, varscan2
- TMEM31 | c.372A>T p.I124= | Silent (SNP) | VAF 15/370 reads (4%) | called by muse, mutect2
- TRH | c.111G>A p.A37= | Silent (SNP) | VAF 50/290 reads (17%) | catalogued as rs577072346, COSV57014591; called by muse, mutect2, varscan2
- TSPAN7 | c.471C>A p.T157= | Silent (SNP) | VAF 74/480 reads (15%) | called by muse, mutect2, varscan2
- UROC1 | c.222C>T p.I74= | Silent (SNP) | VAF 25/244 reads (10%) | catalogued as rs770291107, COSV99332319; called by muse, mutect2, varscan2
- ZFYVE26 | c.4035G>T p.V1345= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs374530573, COSV61324427; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BDNF | c.-21-28C>G | Intron (SNP) | VAF 29/204 reads (14%) | called by muse, mutect2, varscan2
- C1orf220 | n.663G>T | RNA (SNP) | VAF 40/291 reads (14%) | called by muse, mutect2, varscan2
- CCNYL2 | n.1250T>A | RNA (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- CDKN1A | chr6:36677928 G>T | 5'Flank (SNP) | VAF 36/240 reads (15%) | called by muse, mutect2
- CFAP99 | chr4:2458763 G>A | 5'Flank (SNP) | VAF 8/144 reads (6%) | catalogued as rs989709577; called by muse, mutect2
- CLCN5 | c.17-33333G>T | Intron (SNP) | VAF 31/250 reads (12%) | catalogued as COSV65802951; called by muse, mutect2, varscan2
- DNM3 | c.1689+13251C>T | Intron (SNP) | VAF 15/133 reads (11%) | called by mutect2, varscan2
- DST | c.414+6791G>A | Intron (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2, varscan2
- FAM86B3P | n.724C>T | RNA (SNP) | VAF 36/154 reads (23%) | called by muse, mutect2, varscan2
- FAM90A27P | n.1232C>G | RNA (SNP) | VAF 30/428 reads (7%) | called by muse, mutect2
- FAM9B | c.281+93G>C | Intron (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- FER1L4 | n.3963T>A | RNA (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
- GALNT13 | c.1395+37G>A | Intron (SNP) | VAF 13/291 reads (4%) | called by muse, mutect2
- GVINP1 | n.7040G>T | RNA (SNP) | VAF 33/205 reads (16%) | called by muse, mutect2, varscan2
- HTR4 | c.*1589C>T | 3'UTR (SNP) | VAF 20/123 reads (16%) | catalogued as rs145729392; called by muse, mutect2, varscan2
- KEL | c.-56G>A | 5'UTR (SNP) | VAF 12/284 reads (4%) | catalogued as rs1286596407; called by muse, mutect2
- LAMA1 | c.7051-46C>T | Intron (SNP) | VAF 10/199 reads (5%) | called by muse, mutect2
- LINC01546 | n.409G>T | RNA (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- MAPK12 | c.255+22C>A | Intron (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- MFGE8 | c.685+18G>T | Intron (SNP) | VAF 121/370 reads (33%) | called by muse, mutect2, varscan2
- MRPS36P1 | chr3:6770104 C>T | 3'Flank (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- NPEPL1 | c.1001+15C>T | Intron (SNP) | VAF 73/472 reads (15%) | called by muse, mutect2, varscan2
- NTNG2 | c.1054+816G>T | Intron (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2
- PDIA3P1 | n.1229G>T | RNA (SNP) | VAF 10/210 reads (5%) | catalogued as rs587748559; called by muse, mutect2
- PDIA4 | c.88+376G>T | Intron (SNP) | VAF 34/282 reads (12%) | called by muse, mutect2, varscan2
- PREP | c.-143A>G | 5'UTR (SNP) | VAF 8/168 reads (5%) | catalogued as COSV99053514; called by muse, mutect2
- RNA5S17 | chr1:228650574 C>G | 5'Flank (SNP) | VAF 135/565 reads (24%) | catalogued as rs762340169; called by muse, mutect2, varscan2
- SERPINA4 | c.-18+75C>A | Intron (SNP) | VAF 13/340 reads (4%) | called by muse, mutect2
- SIGLEC17P | n.758G>T | RNA (SNP) | VAF 32/226 reads (14%) | called by muse, mutect2, varscan2
- SNORD115-19 | n.82C>T | RNA (SNP) | VAF 30/194 reads (15%) | catalogued as rs188758741; called by muse, mutect2, varscan2
- SNORD116-29 | chr15:25101557 C>G | 5'Flank (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- STMP1 | chr7:135660377 A>C | 5'Flank (SNP) | VAF 56/340 reads (16%) | called by muse, mutect2, varscan2
- TAF2 | c.3109-529G>T | Intron (SNP) | VAF 18/239 reads (8%) | called by muse, mutect2
- TSC2 | c.2742+35G>T | Intron (SNP) | VAF 47/405 reads (12%) | called by muse, mutect2, varscan2
- VRK3 | chr19:49972049 C>A | 3'Flank (SNP) | VAF 18/171 reads (11%) | called by muse, mutect2, varscan2
- WFS1 | c.315+37G>T | Intron (SNP) | VAF 28/250 reads (11%) | called by muse, mutect2, varscan2
- XIAP | chrX:123860188 G>T | 5'Flank (SNP) | VAF 93/611 reads (15%) | called by muse, mutect2, varscan2
- ZNF566 | c.9+32G>T | Intron (SNP) | VAF 23/141 reads (16%) | catalogued as rs374667527; called by muse, mutect2, varscan2
- ZNF880 | c.-26G>A | 5'UTR (SNP) | VAF 25/210 reads (12%) | called by muse, mutect2, varscan2
